Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6012, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6012-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Lesion of vocal cord/throat dysphagia

PROCEDURE: Direct laryngoscopy, esophagoscopy

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMO RADIATION: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

FINAL DIAGNOSIS:

LARYNX, RIGHT, BIOPSY

INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, WITH FOCAL ANGIOLYMPHATIC INVASION.

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is submitted in buffered formalin identified as "right larynx biopsy" and is labeled with the patient's name and initials xxx.

Fragment (s): Aggregate tissue

Size (s): 3.0 x 1.5 x 0.3 cm aggregate

Cassette (s): A and B (totally submitted)

[REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

[REDACTED]

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

[page 2 of 2]
ranges from a minimum of [REDACTED] a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Right Larynx Biopsy

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

HHE x 1 A

H&E x 1 A

HHE x 1 B

H&E x 1 B

[REDACTED]

Source: NCI Genomic Data Commons file c7b692f4-4361-4c5e-882d-5425c29ada87 (TCGA-CN-6012.D754C784-4D68-4D19-9EF8-000FB4575201.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).